Somatic mutation profile of tumor specimen C3N-00555-02 (aliquot CPT0068280006) from CPTAC case C3N-00555, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.6 years (21,771 days).
Specimen C3N-00555-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4853eb0c-dfe2-49fc-aa6c-66a29f3df2d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00555-71 (Blood Derived Normal), aliquot CPT0068390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d899550-bca6-4bf1-a6b3-bc80d191f6e8

The open-access MAF lists 325 somatic variants for this specimen: 224 protein-altering or splice-affecting, 58 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 58, Intron 21, Frame Shift Del 13, Nonsense Mutation 11, RNA 7, Splice Region 6, 3'UTR 5, 3'Flank 5, Frame Shift Ins 3, Splice Site 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNA1 | c.677C>G p.T226R | Missense Mutation (SNP) | VAF 163/469 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs28933383, CM076245, CM962692, CM993940, COSV66836391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.439del p.V147Lfs*23 | Frame Shift Del (DEL) | VAF 91/241 reads (38%) | catalogued as rs1567553924, COSV52675604, COSV52980910; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC2 | c.1057C>A p.R353S | Missense Mutation (SNP) | VAF 117/494 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV64970961; called by muse, mutect2, varscan2
- ADAD1 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1330298013, COSV56642504; called by muse, mutect2, varscan2
- ADAMTS19 | c.629C>G p.T210R | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs772541574; called by muse, mutect2, varscan2
- ADGRA2 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200522621; called by muse, mutect2, varscan2
- ADGRV1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs186234349; called by muse, mutect2, varscan2
- AMIGO2 | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs1450754179, COSV99873566; called by muse, mutect2, varscan2
- ANAPC1 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs148969655; called by muse, mutect2, varscan2
- ARF3 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.093); catalogued as rs752332270; called by muse, mutect2, varscan2
- ASPM | c.6995G>C p.R2332P | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54142558; called by muse, mutect2, varscan2
- ATG2B | c.4786G>A p.V1596I | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV55889324; called by muse, mutect2, varscan2
- BGN | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1011782727; called by muse, mutect2, varscan2
- CACNA1C | c.3912C>T p.N1304= | Splice Region (SNP) | VAF 27/219 reads (12%) | catalogued as rs1221384071, COSV59774652; called by muse, mutect2, varscan2
- CARMIL1 | c.3629G>T p.G1210V | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV61515891; called by muse, varscan2
- CCDC178 | c.2249C>T p.A750V (on ENST00000383096 / NM_001105528.3; = p.A712V on NM_198995.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55787158; called by muse, mutect2, varscan2
- CD47 | c.746A>T p.Y249F | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs755738494; called by muse, mutect2, varscan2
- CLASP1 | c.4198C>T p.H1400Y | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99755179; called by muse, varscan2
- COL11A1 | c.3367G>C p.G1123R | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62183236; called by muse, mutect2, varscan2
- CORIN | c.3050C>A p.P1017H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56697693; called by muse, mutect2, varscan2
- CPT1A | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750451063; called by muse, mutect2, varscan2
- DGLUCY | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs760820803, COSV99824472; called by muse, mutect2, varscan2
- DIPK2A | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 76/268 reads (28%) | catalogued as rs1478006206; called by muse, mutect2, varscan2
- DNAH5 | c.7484C>T p.A2495V | Missense Mutation (SNP) | VAF 80/388 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768364281, COSV54240172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as rs1383749479; called by muse, mutect2, varscan2
- EFCAB8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as rs779770974; called by muse, mutect2
- ELFN1 | c.1777G>T p.V593F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs780767565; called by muse, mutect2, varscan2
- FBXO40 | c.2108C>A p.P703Q | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV57521711; called by muse, mutect2, varscan2
- FSIP2 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390911813, COSV58099404; called by muse, mutect2
- FYB1 | c.242del p.P81Rfs*3 | Frame Shift Del (DEL) | VAF 230/726 reads (32%) | catalogued as COSV60948233; called by mutect2, pindel, varscan2
- GBX2 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.235); catalogued as rs1183275622; called by muse, varscan2
- GGT1 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs187334067; called by muse, mutect2, varscan2
- GPR78 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768492391; called by muse, mutect2, varscan2
- GPR88 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 141/310 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as rs79510999; called by muse, mutect2, varscan2
- HMCN1 | c.8275G>T p.D2759Y | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54901419; called by muse, mutect2, varscan2
- IGF2R | c.6983A>G p.K2328R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766588478; called by muse, mutect2, varscan2
- IL10 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 112/506 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745923816; called by muse, mutect2, varscan2
- INSYN1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764600744; called by muse, mutect2
- KIF5B | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100192465; called by muse, mutect2, varscan2
- LAMA5 | c.9225G>T p.P3075= | Splice Region (SNP) | VAF 38/168 reads (23%) | catalogued as COSV53353345; called by muse, mutect2, varscan2
- LAMB4 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52730276; called by muse, mutect2, varscan2
- LGR6 | c.2725G>T p.A909S (on ENST00000367278 / NM_001017403.1; = p.A857S on NM_021636.3) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs759945217; called by muse, mutect2, varscan2
- MACF1 | c.20197A>G p.T6733A (on ENST00000372915; = p.T4778A on NM_012090.5) | Missense Mutation (SNP) | VAF 80/175 reads (46%) | catalogued as rs1353302955; called by muse, mutect2, varscan2
- MS4A14 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55738859; called by muse, mutect2, varscan2
- MS4A5 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55741863; called by muse, mutect2, varscan2
- MTSS1 | c.2089G>C p.D697H | Missense Mutation (SNP) | VAF 119/513 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as rs1206319327; called by muse, mutect2, varscan2
- MYRIP | c.1319C>A p.P440Q | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1486641882; called by muse, mutect2, varscan2
- NOS1AP | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 26/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62634858; called by muse, mutect2
- OR13C3 | c.737del p.F246Sfs*13 | Frame Shift Del (DEL) | VAF 66/235 reads (28%) | catalogued as rs764206746; called by pindel, varscan2
- OR2T2 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 147/1300 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV61617691, COSV61617841; called by muse, mutect2, varscan2
- OR8J1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs773221666; called by muse, mutect2, varscan2
- PCDH15 | c.5755T>A p.C1919S | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.027); catalogued as rs376353049; called by muse, mutect2, varscan2
- PCDHA9 | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 154/595 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV65323332; called by muse, mutect2, varscan2
- PHF14 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1471554283, COSV68857752; called by muse, mutect2, varscan2
- PLEKHA6 | c.1354C>A p.R452S | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55329715; called by muse, mutect2, varscan2
- POM121L2 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV66276946; called by muse, mutect2
- PPFIA3 | c.1565C>A p.P522H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV100495153; called by muse, mutect2, varscan2
- PXK | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100244469; called by muse, mutect2, varscan2
- R3HCC1L | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1467619208; called by muse, mutect2, varscan2
- RXRB | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354956520, COSV63399631; called by muse, mutect2, varscan2
- RYR3 | c.8631C>G p.F2877L (on ENST00000389232; = p.F2878L on NM_001036.6) | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1488184976, COSV66804630; called by muse, mutect2, varscan2
- SCLY | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); catalogued as rs906844263; called by muse, mutect2
- SEMA3A | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1273560279; called by muse, mutect2
- SPRR4 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 143/507 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs1433341830; called by muse, mutect2, varscan2
- SV2B | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV57700839; called by muse, mutect2, varscan2
- THBS2 | c.1638G>C p.R546S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1291043770; called by muse, mutect2
- TMEM41B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771178606, COSV55154423; called by muse, mutect2, varscan2
- TRPS1 | c.2677G>A p.G893S (on ENST00000220888 / NM_001330599.2; = p.G906S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/583 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750437220; called by muse, mutect2, varscan2
- TSEN54 | c.286-8C>T | Splice Region (SNP) | VAF 125/483 reads (26%) | catalogued as rs886053395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.11664G>A p.M3888I | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs779930040; called by muse, mutect2, varscan2
- ZNF418 | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as rs773080623, COSV101268937; called by muse, varscan2
- ZNF626 | c.1307A>T p.Q436L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs782820934, COSV74129453; called by muse, varscan2
- ABCA10 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSF3 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADCY3 | c.3212C>A p.A1071D | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP9 | c.4613del p.I1538Nfs*9 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ANKRD12 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ANKRD30A | c.599C>A p.A200E (on ENST00000611781; = p.A144E on NM_052997.2) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ANO2 | c.161A>T p.Q54L (on ENST00000356134 / NM_001278597.3; = p.Q58L on NM_001278596.3) | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF1 | c.5027C>G p.S1676* | Nonsense Mutation (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- ARL13A | c.516A>C p.E172D | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTN1 | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATF6 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BEND3 | c.2109G>T p.L703F | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- C12orf40 | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- C7 | c.2059C>A p.R687S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CARMIL1 | c.3628G>C p.G1210R | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, varscan2
- CARMIL3 | c.2695G>C p.G899R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CASP12 | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC173 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- CDH3 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 296/691 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CFAP221 | c.2031G>T p.L677F | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CFAP46 | c.3201G>T p.K1067N | Missense Mutation (SNP) | VAF 109/409 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CHD3 | c.3149A>G p.Y1050C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLASP1 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCNKA | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDN1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMTR2 | c.45dup p.A16Rfs*10 | Frame Shift Ins (INS) | VAF 16/112 reads (14%) | called by mutect2, pindel
- CNBD1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CNNM3 | c.1747A>T p.T583S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CPN2 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRACR2A | c.1099A>T p.K367* | Nonsense Mutation (SNP) | VAF 46/291 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.10618T>C p.Y3540H (on ENST00000520002; = p.Y3539H on NM_033225.6) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNA2 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, varscan2
- CYBB | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 140/315 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CYP2A6 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYP2F1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP3A4 | c.192T>A p.C64* | Nonsense Mutation (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- DDX58 | c.296del p.K99Sfs*9 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | called by mutect2, pindel, varscan2
- DNAH9 | c.1805A>G p.K602R | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- DTWD1 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DYNC2H1 | c.1269A>T p.K423N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DZIP3 | c.1172A>C p.N391T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); called by muse, varscan2
- EIF2B4 | c.1264C>A p.Q422K (on ENST00000347454 / NM_001034116.2; = p.Q421K on NM_015636.3) | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- EIF4E | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- EXOC6 | c.274-2A>T p.X92_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- FAP | c.2041A>C p.T681P | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT1 | c.2123_2124del p.S708Cfs*9 | Frame Shift Del (DEL) | VAF 33/175 reads (19%) | called by pindel, varscan2
- FCRL6 | c.452del p.K151Rfs*115 | Frame Shift Del (DEL) | VAF 15/172 reads (9%) | called by mutect2, pindel
- FKTN | c.1242A>T p.E414D | Missense Mutation (SNP) | VAF 158/499 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FMO1 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- FOLH1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FREM2 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FSTL4 | c.1419G>T p.Q473H | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FZD10 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.723); called by muse, mutect2
- GABRA2 | c.559T>A p.Y187N | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GALNT9 | c.353_355dup p.G118_Y119insC | In Frame Ins (INS) | VAF 160/284 reads (56%) | called by pindel, varscan2
- GCNT7 | c.882G>C p.W294C | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GET4 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GFPT2 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- GOLGA8O | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- GRIK2 | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by mutect2, varscan2
- GRM4 | c.277del p.R93Afs*25 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- GTSF1 | c.35A>C p.E12A | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- HEATR6 | c.700-2A>T p.X234_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- HTR1A | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IGLC7 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 233/1037 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IGSF8 | c.1211A>T p.Y404F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL12RB1 | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 66/445 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IQCA1 | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KBTBD12 | c.1633A>C p.T545P | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LIPT2 | c.466+4A>G | Splice Region (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- LMX1A | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.367); called by muse, varscan2
- MAP7 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED10 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MEGF10 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MID1 | c.867G>T p.V289= | Splice Region (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- MINDY3 | c.466dup p.R156Kfs*23 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- MME | c.2195C>A p.A732D | Missense Mutation (SNP) | VAF 118/741 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH4 | c.4561G>A p.A1521T | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NCAN | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST4 | c.1030T>A p.F344I | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NECTIN2 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, varscan2
- NLRP3 | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NLRP3 | c.3067A>T p.K1023* | Nonsense Mutation (SNP) | VAF 52/522 reads (10%) | called by muse, mutect2
- NUTM2A | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 25/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NUTM2G | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- OR13G1 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, varscan2
- OR2M7 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR2T35 | c.412del p.R138Afs*22 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, varscan2
- OR2T35 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by mutect2, varscan2
- OR56A1 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR6K2 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B12 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PARP14 | c.2133A>T p.K711N | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA4 | c.1909T>C p.Y637H | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PCLO | c.13990A>C p.S4664R | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHTF2 | c.1740G>C p.Q580H (on ENST00000248550 / NM_001366089.1; = p.Q542H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PKD2L1 | c.2275C>G p.P759A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKHD1L1 | c.2973C>A p.S991R | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PPFIBP2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPIL3 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- PROB1 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 153/392 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRJ | c.3230-2A>G p.X1077_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | called by muse, varscan2
- RAB6A | c.132A>C p.A44= | Splice Region (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- RELN | c.9482C>A p.P3161H | Missense Mutation (SNP) | VAF 147/529 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHOXF2 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); called by mutect2, varscan2
- RP1 | c.4315A>G p.M1439V | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- SAMD9 | c.1585A>G p.T529A | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SCAF11 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCUBE3 | c.2617A>G p.T873A | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEC14L5 | c.1306A>G p.S436G | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SERPINA3 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC26A7 | c.1666A>T p.N556Y | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SLC29A2 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 25/548 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC8A1 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC9A5 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMG1 | c.10061dup p.L3354Ffs*10 | Frame Shift Ins (INS) | VAF 23/108 reads (21%) | called by mutect2, pindel
- SOAT2 | c.1469G>C p.S490T | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SPATA31A1 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- SPEN | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 213/451 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- STX11 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 171/822 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TBC1D4 | c.2787G>T p.Q929H | Missense Mutation (SNP) | VAF 127/400 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TMEM202 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TMEM225 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM253 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFSF10 | c.846A>C p.*282Yext*12 | Nonstop Mutation (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- TNN | c.35_36del p.G12Afs*47 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, varscan2*
- TRAF3IP1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- TRBV7-1 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TRIML2 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRIP12 | c.5043_5044del p.F1681Lfs*2 | Frame Shift Del (DEL) | VAF 49/198 reads (25%) | called by mutect2, pindel, varscan2
- TRPC5 | c.206T>A p.L69* | Nonsense Mutation (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- TSC22D4 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- TTBK1 | c.292A>T p.R98W | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.5840C>A p.P1947H (on ENST00000591111; = p.P1901H on NM_003319.4) | Missense Mutation (SNP) | VAF 131/440 reads (30%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.4837G>T p.A1613S (on ENST00000591111; = p.A1567S on NM_003319.4) | Missense Mutation (SNP) | VAF 13/191 reads (7%) | PolyPhen benign (0.41); called by muse, mutect2
- UBR3 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC79 | c.4353C>A p.N1451K (on ENST00000393151 / NM_001346218.2; = p.N1274K on NM_020818.5) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UNC80 | c.2617G>C p.V873L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UTRN | c.2853+1del | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by pindel, varscan2
- VCAN | c.8854A>G p.K2952E | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VNN3 | c.485A>T p.N162I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- VSIG10L | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- VSX1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- YTHDF1 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZC3H18 | c.1612del p.A538Lfs*100 | Frame Shift Del (DEL) | VAF 83/260 reads (32%) | called by mutect2, pindel, varscan2
- ZFPM2 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF208 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF366 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 168/389 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF418 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.948); called by muse, varscan2
- ZNF469 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF831 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ADGRL2 | c.879A>C p.P293= | Silent (SNP) | VAF 136/602 reads (23%) | called by muse, mutect2, varscan2
- APTX | c.720G>A p.G240= | Silent (SNP) | VAF 141/534 reads (26%) | called by muse, mutect2, varscan2
- B3GNT6 | c.882C>G p.A294= | Silent (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- BRSK1 | c.1959C>G p.G653= | Silent (SNP) | VAF 57/391 reads (15%) | called by muse, mutect2, varscan2
- BUB1B | c.2466T>C p.F822= | Silent (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- CFH | c.2658T>A p.S886= | Silent (SNP) | VAF 27/256 reads (11%) | called by muse, mutect2, varscan2
- CHD6 | c.2967C>T p.T989= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- CSMD1 | c.741G>T p.A247= | Silent (SNP) | VAF 57/262 reads (22%) | catalogued as rs1451857994, COSV68250344; called by muse, mutect2, varscan2
- DNMBP | c.180C>T p.T60= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, varscan2
- EDRF1 | c.3090G>A p.L1030= (on ENST00000356792 / NM_001202438.2; = p.L996= on NM_015608.2) | Silent (SNP) | VAF 89/307 reads (29%) | called by muse, mutect2, varscan2
- EPN1 | c.432G>T p.R144= | Silent (SNP) | VAF 89/330 reads (27%) | called by muse, mutect2, varscan2
- FAM47A | c.786A>T p.R262= | Silent (SNP) | VAF 74/158 reads (47%) | called by muse, mutect2, varscan2
- GAD2 | c.1116G>A p.L372= | Silent (SNP) | VAF 42/213 reads (20%) | catalogued as COSV52167276; called by muse, mutect2, varscan2
- GDF7 | c.18C>A p.A6= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs781134510; called by muse, mutect2, varscan2
- GLI2 | c.4707C>G p.T1569= (on ENST00000361492 / NM_001374353.1; = p.T1586= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- HOXA9 | c.159G>T p.P53= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs368735379; called by muse, mutect2, varscan2
- HRH3 | c.825T>C p.Y275= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- IL17A | c.267C>T p.I89= | Silent (SNP) | VAF 63/267 reads (24%) | called by muse, mutect2, varscan2
- LAMB1 | c.2487C>A p.V829= | Silent (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3409A>C p.R1137= | Silent (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- LRBA | c.4107C>A p.V1369= | Silent (SNP) | VAF 24/180 reads (13%) | called by muse, varscan2
- LRRC31 | c.936A>G p.L312= | Silent (SNP) | VAF 111/318 reads (35%) | catalogued as rs1301688309; called by muse, mutect2, varscan2
- LRRC4C | c.90G>T p.L30= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs377286641; called by muse, mutect2, varscan2
- LRRFIP1 | c.606T>C p.L202= (on ENST00000392000 / NM_001137552.2; = p.L178= on NM_004735.4) | Silent (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- LUC7L3 | c.1298A>G p.*433= | Silent (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- MAST3 | c.348T>A p.L116= | Silent (SNP) | VAF 41/362 reads (11%) | called by muse, mutect2, varscan2
- MEGF11 | c.216G>A p.T72= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs977780686; called by muse, mutect2
- MTRR | c.534A>G p.R178= (on ENST00000264668; = p.R151= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- MYH13 | c.4788G>T p.R1596= | Silent (SNP) | VAF 55/204 reads (27%) | called by muse, mutect2, varscan2
- NOS2 | c.1671G>A p.L557= | Silent (SNP) | VAF 121/318 reads (38%) | called by muse, mutect2, varscan2
- NUP155 | c.951T>A p.S317= (on ENST00000231498 / NM_153485.3; = p.S258= on NM_004298.4) | Silent (SNP) | VAF 174/512 reads (34%) | called by muse, mutect2, varscan2
- OR4K13 | c.12A>G p.A4= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, varscan2
- OR5T2 | c.630C>A p.A210= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- OR8B12 | c.768C>T p.F256= | Silent (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- PARD3 | c.1488G>T p.R496= | Silent (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1899C>T p.R633= | Silent (SNP) | VAF 261/663 reads (39%) | catalogued as COSV50756749; called by muse, mutect2, varscan2
- PIWIL3 | c.136C>A p.R46= | Silent (SNP) | VAF 49/206 reads (24%) | called by muse, mutect2, varscan2
- PIWIL3 | c.135C>A p.P45= | Silent (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- PLAG1 | c.1338G>A p.Q446= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- PLD2 | c.102G>A p.E34= | Silent (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- POTEA | c.1164C>T p.N388= (on ENST00000519951 / NM_001005365.2; = p.N342= on NM_001002920.1) | Silent (SNP) | VAF 37/293 reads (13%) | catalogued as rs113208106; called by muse, mutect2, varscan2
- PTPRT | c.3024C>T p.Y1008= | Silent (SNP) | VAF 26/322 reads (8%) | catalogued as rs369837092; called by muse, mutect2
- R3HDML | c.564T>C p.S188= | Silent (SNP) | VAF 73/299 reads (24%) | catalogued as rs779485011; called by muse, mutect2, varscan2
- RTL1 | c.513C>A p.I171= | Silent (SNP) | VAF 90/301 reads (30%) | called by muse, mutect2, varscan2
- SERPINA5 | c.15C>G p.L5= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2
- SLC17A6 | c.390C>A p.S130= | Silent (SNP) | VAF 51/144 reads (35%) | called by muse, mutect2, varscan2
- SMAP2 | c.627G>A p.K209= | Silent (SNP) | VAF 82/186 reads (44%) | called by muse, mutect2, varscan2
- SNRNP70 | c.1029A>G p.P343= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs1419262736; called by muse, mutect2, varscan2
- SPTBN4 | c.2403C>T p.F801= | Silent (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- STARD9 | c.4458C>T p.A1486= | Silent (SNP) | VAF 35/330 reads (11%) | called by muse, mutect2, varscan2
- SUGP2 | c.1797A>G p.E599= | Silent (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- TBC1D10C | c.1107C>T p.A369= | Silent (SNP) | VAF 81/317 reads (26%) | catalogued as rs769447754; called by muse, mutect2, varscan2
- TTN | c.44532C>T p.Y14844= (on ENST00000591111; = p.Y7420= on NM_003319.4) | Silent (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- VASH2 | c.342C>A p.I114= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- VN1R2 | c.696T>C p.T232= | Silent (SNP) | VAF 63/430 reads (15%) | catalogued as rs1299035884; called by muse, mutect2, varscan2
- ZFHX4 | c.9837T>A p.P3279= | Silent (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- ZNF444 | c.912G>C p.A304= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs1176255795; called by muse, mutect2, varscan2
- ZNF880 | c.1584C>T p.V528= | Silent (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81157049 C>A | 3'Flank (SNP) | VAF 127/318 reads (40%) | catalogued as rs1244991209; called by muse, mutect2, varscan2
- AC093802.1 | n.152G>A | RNA (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- AGBL2 | c.98-304G>A | Intron (SNP) | VAF 72/263 reads (27%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.306A>G | RNA (SNP) | VAF 518/912 reads (57%) | called by muse, mutect2, varscan2
- ARHGAP27P2 | n.368C>T | RNA (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- ATF3 | c.349-338C>T | Intron (SNP) | VAF 104/339 reads (31%) | catalogued as rs1487829379; called by muse, mutect2, varscan2
- CD276 | c.-55+6282G>A | Intron (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137016313 A>T | 3'Flank (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- CLRN1 | c.*433A>T | 3'UTR (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- COX7A1 | c.16-184G>A | Intron (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12599G>A | Intron (SNP) | VAF 14/67 reads (21%) | catalogued as rs1238970306; called by muse, mutect2
- FAM21FP | n.1007T>G | RNA (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- HCN1 | c.-32G>A | 5'UTR (SNP) | VAF 87/181 reads (48%) | called by muse, mutect2, varscan2
- JPH4 | c.1151+59A>T | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, varscan2
- KCNQ4 | c.*21C>T | 3'UTR (SNP) | VAF 54/243 reads (22%) | called by muse, mutect2, varscan2
- LINC00574 | n.149T>G | RNA (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11037del | Intron (DEL) | VAF 82/195 reads (42%) | called by mutect2, pindel, varscan2
- MIR1-1HG-AS1 | n.644C>A | RNA (SNP) | VAF 192/585 reads (33%) | called by muse, mutect2, varscan2
- MON1B | c.476-30A>G | Intron (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- MRM2 | c.-20T>A | 5'UTR (SNP) | VAF 25/105 reads (24%) | catalogued as rs1229109514; called by muse, mutect2, varscan2
- MUC19 | n.6037T>C | RNA (SNP) | VAF 57/235 reads (24%) | called by muse, mutect2, varscan2
- NHSL1 | c.676+5005del | Intron (DEL) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- NRXN2 | c.1197+50dup | Intron (INS) | VAF 36/154 reads (23%) | catalogued as rs763412451; called by mutect2, varscan2
- OOSP2 | c.348-205A>T | Intron (SNP) | VAF 18/129 reads (14%) | catalogued as rs974235716; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120844 T>A | 3'Flank (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- PDZRN3 | c.918+33196T>C | Intron (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577431 G>T | 3'Flank (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75786155 G>T | 3'Flank (SNP) | VAF 46/343 reads (13%) | catalogued as rs765598085; called by muse, mutect2, varscan2
- RNF135 | chr17:30971038 C>T | 5'Flank (SNP) | VAF 71/312 reads (23%) | called by muse, mutect2, varscan2
- RPL3 | c.952-168_952-166del | Intron (DEL) | VAF 55/215 reads (26%) | called by mutect2, pindel, varscan2
- SLC25A29 | c.79-2273G>A | Intron (SNP) | VAF 31/242 reads (13%) | catalogued as rs897604356; called by muse, mutect2, varscan2
- SMPD4 | c.1571-96C>T | Intron (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- SYT7 | c.215+8928C>G | Intron (SNP) | VAF 32/233 reads (14%) | called by muse, mutect2, varscan2
- TBCA | c.54-6957G>A | Intron (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- TBL3 | c.*317_*319dup | 3'UTR (INS) | VAF 58/129 reads (45%) | called by mutect2, varscan2
- TINAG | c.*42C>A | 3'UTR (SNP) | VAF 35/148 reads (24%) | catalogued as COSV99450370; called by muse, mutect2
- TP63 | c.1349+29G>A | Intron (SNP) | VAF 75/551 reads (14%) | catalogued as COSV53203627; called by muse, mutect2, varscan2
- TPTE2 | c.1395+600G>T | Intron (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- UBN1 | chr16:4847338 G>A | 5'Flank (SNP) | VAF 103/261 reads (39%) | called by muse, mutect2, varscan2
- VNN3 | c.*63A>G | 3'UTR (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2
- YBX1 | c.167-217C>G | Intron (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- Y_RNA | chr12:54102424 C>G | 5'Flank (SNP) | VAF 71/354 reads (20%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+43775G>T | Intron (SNP) | VAF 98/398 reads (25%) | called by muse, mutect2, varscan2
